Gene-level copy-number profile of tumor specimen TCGA-C5-A2LX-01A from TCGA case TCGA-C5-A2LX, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 54.9 years (20,070 days).
Specimen TCGA-C5-A2LX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.90bcc542-fc4d-4728-a79e-92d2d14ffbee.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-C5-A2LX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5bb86414-5266-46a0-9342-c82b90b87684

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 4,079; copy number 2: 17,826; copy number 3: 31,531; copy number 4: 4,493; copy number 5: 276; copy number 6: 1,405; copy number 7: 191; copy number 10: 2; copy number 11: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-C5-A2LX-01A-11D-A18H-01): tumor purity 0.61, ploidy 2.77, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 209 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:235,131,183–235,344,532, 5 genes, copy number 7 (within-gene range 4–7): RBM34, ARID4B, MIR4753, RPL23AP23, GGPS1.
- chr1:235,336,806–235,337,087, 1 gene, copy number 7: AL391994.1.
- chr3:172,505,508–177,228,000, 48 genes, copy number 7 (within-gene range 6–7): TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2, RNU6-547P, AC108667.2, ECT2, SNORA72, RNU4-4P, ATP5MC1P4, AC108667.1, SPATA16, AC068759.1, NLGN1, AC092967.1, NLGN1-AS1, RN7SKP234, ANAPC15P2, AC069218.1, NAALADL2, RN7SKP40, EEF1B2P8, NAALADL2-AS3, NAALADL2-AS2, MIR4789, RNU6-1233P, AC008180.3, RNU4-91P, AC119744.1, UBE2V1P2, RNU6-1317P, NAALADL2-AS1, AC104640.1, ACTG1P23, EI24P1, AC104640.2, AC117434.1, LINC01208, MIR7977, RNA5SP147, LINC01209, MTND5P15, TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P.
- chr3:194,584,004–198,222,513, 137 genes, copy number 7 (broad region; genes not listed).
- chr12:118,149,801–118,372,907, 2 genes, copy number 10 (within-gene range 4–10): TAOK3, RPS2P5.
- chr17:45,108,959–45,327,497, 16 genes, copy number 11: PLCD3, MIR6784, ACBD4, AC142472.1, HEXIM1, AC138150.1, HEXIM2, AC138150.2, AC008105.3, FMNL1, AC008105.1, AC008105.2, MAP3K14-AS1, SPATA32, MAP3K14, RNA5SP443.

Autosomal genes at a single copy (total copy number 1): 3,003. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
